Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8264, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8264-01B (Primary Tumor).

[page 1 of 2]
[REDACTED]

Pre-Op Diagnosis
Prostate cancer
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Two parts

Container labeled [REDACTED] - prostate" is a 41 gram previously inked previously partially sectioned moderately distorted prostate gland with attached bilateral seminal vesicles. On reconstruction this measures approximately 5.0 x 3.9 x 3.5 cm and has a shaggy capsule. The urethra appears to be grossly patent. On sectioning there is a lobulated focally nodular gray tan cut surface without discrete gross mass lesion. The seminal vesicles together are 6.4 x 2.4 x 1.0 cm. These have a lobulated outer surface with multicystic gray tan to pink fibrotic cut surface. No gross mass lesions are identified. Also received in the same container are three tissue cassettes labeled [REDACTED]. Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

[REDACTED]

[page 2 of 2]
Container labeled "[REDACTED] 2 - bilateral pelvic lymph nodes possible clip on left lymph nodes" are 6.6 x 4.5 x 1.0 cm tan pink to yellow fibroadipose tissue fragments without orientation. A localization clip is not identified on any of the portions. On sectioning there are two poorly defined pink yellow nodular areas 1.0 and 2.6 cm. The smaller is submitted labeled A, larger submitted labeled B.

[REDACTED]
Microscopic Description:
See diagnosis.

Final Diagnosis

Prostate gland, radical prostatectomy:

Tumor characteristics:

Histologic type: Adenocarcinoma, conventional type.

Prostate size: 41 grams.

Tumor quantitation: Malignancy is present in both right and left lobes, and accounts for an estimated 30% of the total prostate volume.

Gleason grade:

Primary pattern: 4/5

Secondary pattern: 5/5

Total Gleason score: 9/10

Extraprostatic extension: Present, in the bladder margin and prostate base.

Seminal vesicle involvement: Present.

Lymphovascular space invasion: Present.

Perineural invasion: Present.

High grade PIN: Present focally.

Treatment effect: Not identified

Surgical margin status:

The inked surgical margin is involved focally in the region of the bladder margin.

Lymph node status:

Total number of lymph nodes received (see part 2): 2

Total number of lymph nodes containing metastatic carcinoma: 1

Other:

Changes correspond to those in prior needle core biopsies,

[REDACTED]
pTN stage: pT3a,b, N1

Lymph nodes, pelvic, excision:

Metastatic adenocarcinoma, one of two nodes.

The smaller of the two nodes is the positive node. [REDACTED] SPC-A

[REDACTED]
Comments

The malignancy is high grade in most areas. There are some areas of Gleason grade 3 tumor present as well, in addition to the more extensive higher grades.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED], who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

[REDACTED] M.D.

[REDACTED]

Source: NCI Genomic Data Commons file 62de0231-45c1-4680-b84d-e310224cdc86 (TCGA-HC-8264.147B5116-AE7B-4C43-8E6D-3A0064F28902.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).